Surgical pathology report (de-identified scan), TCGA case TCGA-MK-A4N9, project TCGA-THCA (Thyroid Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MK-A4N9-01A (Primary Tumor).

[page 1 of 3]
Results

Collection Information

Collection Date

Collection Time

Resulting Agency

SURGICAL PATHOLOGY

ICD-O-3
Carcinoma, papillary Thyroid
826613
Site:
Thyroid, NBS C73.9
JW 11/29/12

PATHOLOGIC DIAGNOSIS

A. THYROID, TOTAL THYROIDECTOMY:

- PAPILLARY CARCINOMA, MULTIFOCAL (RIGHT 2.1 CM, ISTHMUS 2.6 CM, LEFT 0.4 CM) WITH EXTRATHYROIDAL EXTENSION, SURGICAL MARGINS AND LYMPHOVASCULAR INVASION NEGATIVE
- PERICAPSULAR LYMPH NODES NEAR ISTHMUS, NO PATHOLOGIC DIAGNOSIS (0/3)
- ONE PARATHYROID IDENTIFIED, LEFT SIDE

B. LYMPH NODES, RIGHT PARATRACHEAL, DISSECTION:

- METASTATIC PAPILLARY CARCINOMA (1/4)
- PARATHYROID IDENTIFIED

C. LYMPH NODES, LEFT PARATRACHEAL, DISSECTION:

- NO PATHOLOGIC DIAGNOSIS (0/2)
- PARATHYROID IDENTIFIED

Staff Pathologist

Comment

TUMOR STAGING FORM:

T3, N1a, MX, STAGE I (less than 45 years old)

Pertinent Clinical Information

Papillary thyroid cancer.

[page 2 of 3]
Gross Description

Specimen Material: A- Total thyroidectomy and pretracheal lymph node, B- Right paratracheal lymph node for permanent, C- Left paratracheal lymph node for permanent.

The case is received in three parts labeled with the patient's name, medical record number and given accession number

and it is accompanied by a requisition form labeled with the same name and same accession number.

Part A: The specimen is received in one container labeled as "TOTAL THYROIDECTOMY PRETRACHEAL LYMPH NODE". The specimen is a 160 gram, 9.8 cm

right to left, 6.4 cm superior to inferior, and 1.7 cm medial to lateral total thyroid with a possible attached node measuring 3.5 x 2.4 x 1.1 cm. The surface of the thyroid is tan-red to tan-brown, multinodular, hard and hyperemic. There are no parathyroid glands identified. The specimen is inked blue anterior and black deep. The right lobe at the inferior aspect displays a tan-red to tan-brown, finely nodular ovoid, peripheral calcification smooth and glistening 2.1 x 1.8 x 1.2 cm abutting the margin. The left lobe displays a 0.3 cm tan-white to tan-yellow calcification abutting the superficial surface. The isthmus displays tan-pink firm tissue measuring 3.0 x 2.6 x 1.6 cm with 0.4 cm calcification, 0.2 cm from the superficial surface. The possible lymph node is 2.4 x 2.3 x 1.3 cm with a cut surface tan-yellow to tan-gray, fine nodular, fibroadipose tissue. No hemorrhage or necrosis are identified.

Representative sections are submitted as follows:

- A1: right lobe superior, uninvolved
- A2: right lobe middle area of calcification
- A3: right lobe tumor to margin
- A4: left lobe superior, uninvolved
- A5: left lobe medial calcification of possible additional tumor
- A6: left lobe inferior, bisected slice
- A7-A9: isthmus, additional tumor
- A10: possible additional lymph node
- A11-A12: largest, possible node bisected with tan nodular tissue

Part B: The specimen is received in formalin labeled as "RIGHT PARATRACHEAL LYMPH NODES FOR PERMANENT". The specimen consists of a tan-yellow to tan-brown multinodular, firm piece of adipose tissue measuring 3.1 x 2.4 x 0.3 cm. Six possible lymph nodes are identified measuring from 1.0 x 0.7 x 0.2 cm to 0.2 x 0.2 x 0.1 cm. Two lymph nodes are bisected and the cut surface displays a tan-yellow a tan-brown irregular surface.

Representative sections are submitted as follows: two bisected possible

[page 3 of 3]
lymph nodes in cassette B1, two possible lymph nodes in cassette B2, and two possible lymph nodes in cassette B3.

Part C: The specimen is received in formalin labeled as "LYMPH NODE, PART C". The specimen consists of tan-yellow to tan-pink, 1.6 x 1.4 x 1.2 cm, firm multinodular piece of adipose tissue. Two possible lymph nodes are identified measuring 0.8 x 0.5 x 0.2 cm and 0.5 x 0.4 x 0.1 cm.

Representative sections are submitted as follows:

C1: one possible lymph node

C2: one possible lymph node

Pathology Resident

Microscopic Description

A-C: Performed.

This case was reviewed by the staff pathologist listed below.

Pathology Resident

****Electronically Signed Out****

Staff Pathologist

9/9/12

Source: NCI Genomic Data Commons file b077a0ea-93cc-4855-89a8-b47e2a556a05 (TCGA-MK-A4N9.0C6D4CF3-93B9-4F2B-82E7-7DE9251C82EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).